Somatic mutation profile of tumor specimen TCGA-Q1-A6DW-01A (aliquot TCGA-Q1-A6DW-01A-11D-A32I-09) from TCGA case TCGA-Q1-A6DW, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage I; Tumor grade: GX; Age at diagnosis: 44.4 years (16,200 days).
Specimen TCGA-Q1-A6DW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cf616c4-40b9-4b3f-a279-ebbf2478a67d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q1-A6DW-10B (Blood Derived Normal), aliquot TCGA-Q1-A6DW-10B-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66bd9000-c909-4bc6-8322-079cc773175a

The open-access MAF lists 103 somatic variants for this specimen: 73 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 26, Nonsense Mutation 6, 5'UTR 1, Frame Shift Del 1, 3'UTR 1, Intron 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>G p.S6W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.095); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- DDX3X | c.1592C>T p.T531M (on ENST00000399959; = p.T532M on NM_001356.5) | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795387, COSV67863875; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 63/81 reads (78%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.265A>G p.R89G | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as COSV58144075; called by muse, mutect2, varscan2
- ALDH3A2 | c.331T>C p.W111R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51568292; called by muse, mutect2, varscan2
- ATP2A3 | c.2728T>C p.C910R | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV59234175; called by muse, mutect2, varscan2
- BRWD1 | c.2372C>T p.S791L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs1455940698, COSV60901614; called by muse, mutect2, varscan2
- C5AR2 | c.892C>G p.Q298E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV57257176; called by muse, mutect2, varscan2
- CACNA1E | c.218G>C p.G73A | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV62382290, COSV62414513; called by muse, mutect2, varscan2
- CEP72 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV53796517; called by muse, mutect2, varscan2
- CLSPN | c.3992G>A p.R1331Q | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs115320551, COSV52056680; called by muse, mutect2, varscan2
- CLSPN | c.3401G>A p.R1134Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1487197309, COSV52056309; called by muse, mutect2, varscan2
- CNTN2 | c.2923G>A p.E975K | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV59349914; called by muse, mutect2, varscan2
- COBLL1 | c.1228C>T p.P410S (on ENST00000392717; = p.P372S on NM_014900.5) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV52075003; called by muse, mutect2, varscan2
- COL11A1 | c.3925G>T p.G1309C | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV62194559; called by muse, mutect2
- COL4A2 | c.991G>C p.D331H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV64633004; called by muse, mutect2, varscan2
- CYP46A1 | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV55896308; called by muse, mutect2, varscan2
- DCLRE1B | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.014); catalogued as COSV65813506; called by muse, mutect2, varscan2
- DOCK6 | c.4360G>A p.E1454K | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV53921018; called by muse, mutect2, varscan2
- DPP8 | c.1659C>G p.Y553* (on ENST00000341861 / NM_001320875.2; = p.Y537* on NM_017743.6) | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100202116, COSV55682533; called by muse, mutect2, varscan2
- EPS15 | c.901C>G p.H301D | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV65544918; called by muse, mutect2, varscan2
- FGF22 | c.345C>G p.F115L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.139); catalogued as COSV51261193; called by muse, mutect2, varscan2
- FHOD1 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as COSV50767448; called by muse, mutect2, varscan2
- GLYR1 | c.1494C>G p.F498L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as rs150744754, COSV58928859; called by muse, mutect2, varscan2
- GRM7 | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV63159961; called by muse, mutect2, varscan2
- GSR | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 59/122 reads (48%) | catalogued as COSV55322759; called by muse, mutect2, varscan2
- HSPA6 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.647); catalogued as COSV59062335; called by muse, mutect2, varscan2
- KCNK9 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57278639; called by muse, mutect2, varscan2
- KMT2C | c.7207C>T p.R2403* | Nonsense Mutation (SNP) | VAF 51/73 reads (70%) | catalogued as rs767365126, COSV51459807; called by muse, mutect2, varscan2
- LRIG2 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1372869440, COSV63163809; called by muse, mutect2, varscan2
- LRP1B | c.12120G>A p.M4040I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.192); catalogued as COSV67264588; called by muse, mutect2, varscan2
- LRWD1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs781715136, COSV52960371; called by muse, mutect2
- MAGEB3 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 65/125 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs758651543, COSV64397653; called by muse, mutect2, varscan2
- MAGEC3 | c.1165C>T p.Q389* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV68924197; called by muse, mutect2, varscan2
- MCM10 | c.1670C>T p.S557L (on ENST00000484800 / NM_182751.3; = p.S556L on NM_018518.5) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs558495502, COSV66336403; called by muse, mutect2, varscan2
- MST1R | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs781591594, COSV56568214; called by muse, mutect2, varscan2
- MUC5AC | c.14878G>A p.V4960M | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761229771, COSV64370619; called by muse, mutect2, varscan2
- MYF6 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as COSV57352991; called by muse, mutect2, varscan2
- MYO15A | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.737); catalogued as rs758452758, COSV52763974; called by muse, mutect2, varscan2
- NEIL3 | c.1048C>A p.L350I | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52813070; called by muse, mutect2, varscan2
- NFYC | c.1348G>A p.G450R (on ENST00000308733 / NM_001308114.1; = p.G327R on NM_014223.5) | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.515); catalogued as rs200544060, COSV58126711; called by muse, mutect2, varscan2
- NOTCH3 | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as COSV54646789; called by muse, mutect2, varscan2
- NRK | c.4459G>A p.E1487K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.949); catalogued as COSV54604834; called by muse, mutect2, varscan2
- OR8U1 | c.774G>C p.M258I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56418409; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1810G>A p.E604K (on ENST00000259318 / NM_001136562.3; = p.E835K on NM_007203.5) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs773029802, COSV52180578; called by muse, mutect2, varscan2
- PBX3 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.04); catalogued as COSV60735311; called by muse, mutect2, varscan2
- PDE1C | c.140T>C p.L47S | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58525748; called by muse, mutect2, varscan2
- PKD1 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as rs1339489247, COSV51924118; called by muse, mutect2, varscan2
- PLPBP | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1384327533, COSV60240072; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRRC2A | c.6413G>A p.R2138Q | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1018669734, COSV52989437; called by muse, mutect2, varscan2
- PSD4 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as rs761343089, COSV55526960; called by muse, mutect2, varscan2
- RRP1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs367993051; called by muse, mutect2, varscan2
- SAMD3 | c.1121C>T p.S374L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100695924; called by muse, varscan2
- SEC31A | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs747567461, COSV52341196; called by muse, mutect2, varscan2
- SHOC2 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV54624089; called by muse, mutect2, varscan2
- SLC12A3 | c.997T>A p.W333R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52638350; called by muse, mutect2, varscan2
- SLC26A8 | c.2861G>A p.R954H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs772686449, COSV62887266; called by muse, mutect2, varscan2
- SLC6A9 | c.1324G>A p.V442M (on ENST00000360584 / NM_201649.4; = p.V388M on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs755321679, COSV62211918; called by muse, mutect2, varscan2
- SPRED2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1465584619, COSV62695407; called by muse, mutect2, varscan2
- SPTBN4 | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as COSV58957355; called by muse, mutect2, varscan2
- TACC1 | c.824C>G p.T275R | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.133); catalogued as COSV52527964; called by muse, mutect2, varscan2
- TASOR | c.3262G>T p.E1088* (on ENST00000355628 / NM_001365636.2; = p.E712* on NM_015224.3) | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV62929387; called by muse, mutect2, varscan2
- TEX15 | c.1303G>C p.E435Q (on ENST00000256246; = p.E818Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV56348933, COSV56352360; called by muse, mutect2, varscan2
- TMF1 | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV62740803, COSV62741386; called by muse, mutect2, varscan2
- TRIM61 | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV61417914, COSV61419134; called by mutect2, varscan2
- VWA5A | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV63708156; called by muse, mutect2, varscan2
- ZC3H18 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1161958134, COSV56327525; called by muse, mutect2, varscan2
- ZNF546 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV61259289; called by muse, mutect2, varscan2
- ZNF599 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200075847; called by muse, mutect2, varscan2
- ZXDA | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV62388628; called by muse, mutect2, varscan2
- ZXDB | c.2041T>C p.F681L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV66493361; called by muse, mutect2, varscan2
- EMILIN3 | c.2251_2257delinsA p.D751_Q753delinsK | In Frame Del (DEL) | VAF 24/48 reads (50%) | called by pindel, varscan2*
- WAC | c.1250del p.T417Sfs*3 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
- AGPAT2 | c.714G>A p.A238= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs370950858; called by muse, mutect2, varscan2
- ATP9A | c.2742C>G p.L914= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV58770899; called by muse, mutect2, varscan2
- CCDC30 | c.801C>T p.A267= (on ENST00000340612; = p.A224= on NM_001080850.3) | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- CEACAM16 | c.1275G>T p.G425= | Silent (SNP) | VAF 57/139 reads (41%) | catalogued as COSV69188221; called by muse, mutect2, varscan2
- CRTAM | c.336G>C p.V112= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as rs770449825, COSV57070998; called by muse, mutect2, varscan2
- CSF1 | c.1479C>T p.L493= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV60035086; called by muse, mutect2, varscan2
- FAM171A1 | c.2022C>T p.N674= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV65314456; called by muse, mutect2, varscan2
- GLP1R | c.441C>T p.I147= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs199790397, COSV100952573, COSV64715427; called by muse, mutect2, varscan2
- GP5 | c.1416C>T p.C472= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV59879874; called by muse, mutect2, varscan2
- GPR50 | c.1518C>T p.I506= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV54442209; called by muse, mutect2, varscan2
- IGSF9B | c.1236G>A p.A412= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs1449785128, COSV100318629, COSV58071823; called by muse, mutect2, varscan2
- KDM2B | c.3024G>A p.L1008= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV65644346; called by muse, varscan2
- KIF13B | c.4506G>A p.V1502= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV68094666; called by muse, mutect2, varscan2
- MUC5B | c.9405C>G p.L3135= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as COSV71594703; called by muse, mutect2, varscan2
- MYO3B | c.2106C>T p.L702= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs777858998, COSV58714643; called by muse, mutect2, varscan2
- NOP58 | c.306G>A p.L102= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as COSV51898300; called by muse, mutect2, varscan2
- PCDHA11 | c.1047C>T p.V349= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV56538599; called by muse, mutect2, varscan2
- PLEKHA4 | c.1680G>A p.P560= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as rs377338823; called by muse, mutect2, varscan2
- RBM46 | c.138C>T p.G46= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs747090326, COSV55981460; called by muse, mutect2, varscan2
- SARDH | c.1644C>T p.F548= | Silent (SNP) | VAF 49/129 reads (38%) | catalogued as COSV64099626; called by muse, mutect2, varscan2
- SHISA5 | c.204C>T p.S68= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs149007494; called by muse, mutect2, varscan2
- SLC34A3 | c.1023C>T p.L341= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs1478387696, COSV63187894; called by muse, mutect2, varscan2
- SLC49A4 | c.315C>T p.F105= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as rs1166476372, COSV53749260; called by muse, mutect2, varscan2
- TMC7 | c.2031C>T p.L677= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV58587161; called by muse, mutect2, varscan2
- USP34 | c.10602C>T p.V3534= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100816020; called by muse, mutect2, varscan2
- ZNF248 | c.516G>A p.E172= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV61998401; called by muse, mutect2, varscan2
- MOV10 | c.-1G>A | 5'UTR (SNP) | VAF 23/62 reads (37%) | catalogued as COSV54146907; called by muse, mutect2, varscan2
- NXF5 | n.1024T>C | RNA (SNP) | VAF 57/230 reads (25%) | catalogued as COSV53793057; called by muse, mutect2, varscan2
- PCED1B | c.*2C>T | 3'UTR (SNP) | VAF 19/49 reads (39%) | catalogued as rs752994533, COSV101423640; called by muse, mutect2, varscan2
- SKA2 | c.33+3960C>T | Intron (SNP) | VAF 10/37 reads (27%) | catalogued as COSV51878838; called by muse, mutect2, varscan2
